Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A5ET, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A5ET-01A (Primary Tumor).

Index	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount per container	Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
				male	Caucasian (White)	Glioma		Brain, right, frontal lobe	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Oligodendroglioma	2	n/a	n/a	n/a	none	n/a	80
				male	Caucasian (White)	Glioma		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

ICD-O-3
Oligodendroglioma NOS
9450/3
Site: (R) Brain, supratentorial
JW 4/2/13 C71.0

Source: NCI Genomic Data Commons file b5bb4c49-811f-4f37-9364-9f8e869d97cb (TCGA-P5-A5ET.A28115C7-0F60-442C-BE10-8B93D06F5CEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).